CCDI case PBCVDN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/7f930999-4d33-4cdf-9646-99a021fd33dc

Demographics
Sex at birth: male.

Biospecimens (2 samples)
- Sample 0E0CT7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E0JS3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
